Somatic mutation profile of tumor specimen TCGA-CN-4730-01A (aliquot TCGA-CN-4730-01A-01D-1434-08) from TCGA case TCGA-CN-4730, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.5 years (22,828 days).
Specimen TCGA-CN-4730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c0e9289-a65f-48d3-8122-b98485758818.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4730-10A (Blood Derived Normal), aliquot TCGA-CN-4730-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8479d381-3419-41e7-8639-98e6114f71db

The open-access MAF lists 165 somatic variants for this specimen: 128 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 36, Nonsense Mutation 11, Frame Shift Ins 3, Splice Site 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1177C>T p.R393* (on ENST00000281708 / NM_001349798.2; = p.R313* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 96/147 reads (65%) | hotspot (GDC flag); catalogued as COSV55892695; called by muse, mutect2, varscan2
- AACS | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99907708; called by muse, mutect2, varscan2
- ADCY9 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs778333072, COSV99569267; called by muse, mutect2, varscan2
- AIP | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.249); catalogued as COSV99653492; called by muse, mutect2, varscan2
- ALPK1 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV99452952; called by muse, mutect2, varscan2
- ANKRD11 | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs758824643, COSV56359877; called by muse, mutect2, varscan2
- APOB | c.8540G>T p.G2847V | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV99263341; called by muse, mutect2, varscan2
- ATP1A4 | c.1027G>T p.G343W | Missense Mutation (SNP) | VAF 77/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625916; called by muse, mutect2, varscan2
- AVPR1A | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146757; called by muse, mutect2, varscan2
- BCL9 | c.3133C>T p.P1045S | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV99324399; called by muse, mutect2, varscan2
- BHLHE22 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417577; called by muse, mutect2, varscan2
- BIRC6 | c.6806A>G p.Y2269C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101427788; called by muse, mutect2, varscan2
- BTG2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99305556; called by muse, mutect2, varscan2
- C16orf78 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV100147539; called by muse, mutect2, varscan2
- CABS1 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV99908919; called by muse, mutect2, varscan2
- CACYBP | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100871599; called by muse, mutect2, varscan2
- CASP10 | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 28/144 reads (19%) | catalogued as COSV99628621; called by muse, mutect2, varscan2
- CCDC18 | c.284A>C p.Q95P | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV100159192; called by muse, mutect2, varscan2
- CCPG1 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 187/395 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99379980; called by muse, mutect2, varscan2
- CD28 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs755572170, COSV100142204, COSV100142229; called by muse, mutect2, varscan2
- CDH19 | c.1559C>G p.T520R | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV100050772; called by muse, mutect2, varscan2
- CDH24 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52975264, COSV99398977; called by muse, mutect2, varscan2
- CES1 | c.943-2A>T p.X315_splice | Splice Site (SNP) | VAF 74/186 reads (40%) | catalogued as COSV100828541; called by muse, mutect2, varscan2
- CFAP43 | c.446A>C p.K149T | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs760974312, COSV99530333; called by muse, mutect2, varscan2
- CNTLN | c.2737C>A p.Q913K | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV99262614; called by muse, mutect2, varscan2
- COG5 | c.1894G>C p.E632Q (on ENST00000347053 / NM_001379512.1; = p.E653Q on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99771296; called by muse, mutect2, varscan2
- COL24A1 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100992838; called by muse, mutect2, varscan2
- CPED1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.528); catalogued as COSV100119897; called by muse, mutect2, varscan2
- CUL9 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV52727473; called by muse, mutect2, varscan2
- DNAH5 | c.5389C>G p.Q1797E | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV54242295, COSV99444479; called by muse, mutect2, varscan2
- DNAJC5B | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV99395399; called by muse, mutect2, varscan2
- DNAJC8 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs760200833, COSV99746020; called by muse, mutect2, varscan2
- DTNBP1 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as COSV100160314; called by muse, mutect2, varscan2
- ECHDC1 | c.346G>A p.D116N (on ENST00000531967 / NM_001139510.1; = p.D110N on NM_018479.3) | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100541553, COSV58931145, COSV58933617; called by muse, mutect2, varscan2
- ENOPH1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV99908500; called by muse, mutect2, varscan2
- EPB41L3 | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100548080; called by muse, mutect2, varscan2
- ESYT2 | c.2531C>G p.S844* (on ENST00000613624; = p.S768* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 34/177 reads (19%) | catalogued as COSV99276009, COSV99276281; called by muse, mutect2, varscan2
- FOCAD | c.4822G>A p.V1608M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV58098353; called by muse, mutect2, varscan2
- FTSJ3 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 19/464 reads (4%) | catalogued as COSV100037141; called by muse, mutect2
- GATAD2B | c.1132C>A p.H378N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100897771, COSV64086008; called by muse, mutect2, varscan2
- GDPD3 | c.618G>A p.W206* | Nonsense Mutation (SNP) | VAF 110/356 reads (31%) | catalogued as COSV99531217; called by muse, mutect2, varscan2
- GPD1 | c.499+1G>C p.X167_splice | Splice Site (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99993704; called by muse, mutect2, varscan2
- H3C6 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); catalogued as COSV64519906; called by muse, mutect2, varscan2
- HERPUD1 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 125/758 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100295820; called by muse, mutect2, varscan2
- HLF | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99871929; called by muse, mutect2, varscan2
- HOXA2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99760981; called by muse, mutect2, varscan2
- IL18RAP | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV99961714; called by muse, mutect2, varscan2
- IPO9 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as COSV100843312; called by muse, mutect2, varscan2
- ITGA8 | c.3136C>T p.Q1046* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100958772; called by muse, mutect2, varscan2
- IWS1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 128/311 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99766974; called by muse, mutect2, varscan2
- KATNIP | c.3656C>G p.S1219C | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV99849683; called by muse, mutect2, varscan2
- KBTBD8 | c.1024G>C p.G342R | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99805227; called by muse, mutect2, varscan2
- KLHL1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs1268883107, COSV100916936; called by muse, mutect2, varscan2
- KLHL24 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.186); catalogued as rs766486516, COSV54429062; called by muse, mutect2, varscan2
- KRT6C | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99359807; called by muse, mutect2, varscan2
- KRT78 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV100467085, COSV58851497; called by muse, mutect2, varscan2
- LRP2 | c.13564G>C p.E4522Q | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99786339; called by muse, mutect2, varscan2
- LRP2 | c.2885C>A p.S962* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV55565738, COSV99786319; called by muse, mutect2, varscan2
- LTN1 | c.4218C>G p.Y1406* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100797866; called by muse, mutect2, varscan2
- MAP4K3 | c.1313A>T p.K438M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV99809886; called by muse, mutect2, varscan2
- MED13L | c.5114G>A p.R1705H | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749456428, COSV99927726; called by muse, mutect2, varscan2
- MTA2 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.431); catalogued as COSV53471387, COSV53471974, COSV99544924; called by muse, mutect2, varscan2
- MTA2 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV99544926; called by muse, mutect2, varscan2
- MX1 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs780252858, COSV99912438; called by muse, mutect2, varscan2
- NCK2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.03); catalogued as COSV99255138; called by muse, mutect2, varscan2
- NLRP9 | c.1905A>C p.L635F | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV100242514; called by muse, mutect2, varscan2
- ODF2 | c.2044G>C p.E682Q (on ENST00000434106 / NM_153433.2; = p.E658Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100654407, COSV104417188; called by muse, varscan2
- ODF2 | c.2242G>C p.E748Q (on ENST00000434106 / NM_153433.2; = p.E724Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100654412; called by muse, mutect2, varscan2
- OR11H6 | c.414T>A p.Y138* | Nonsense Mutation (SNP) | VAF 160/378 reads (42%) | catalogued as COSV100209697; called by muse, mutect2
- OR4A47 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV101487048; called by muse, mutect2, varscan2
- OR52E4 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 87/407 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100389125; called by muse, mutect2, varscan2
- OR6K6 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100933672, COSV63743943; called by muse, mutect2, varscan2
- OR8I2 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 127/283 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as rs1429425849, COSV100135835; called by muse, mutect2, varscan2
- PENK | c.377C>A p.A126D | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100152129; called by muse, mutect2, varscan2
- PIFO | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV100868587; called by muse, mutect2, varscan2
- PIP | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs376369577; called by muse, mutect2, varscan2
- PLEC | c.13780G>A p.E4594K (on ENST00000322810 / NM_201380.4; = p.E4484K on NM_000445.5) | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV100509992; called by muse, varscan2
- PLEC | c.11095G>A p.E3699K (on ENST00000322810 / NM_201380.4; = p.E3589K on NM_000445.5) | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100510002; called by muse, mutect2, varscan2
- PLEC | c.10408G>A p.D3470N (on ENST00000322810 / NM_201380.4; = p.D3360N on NM_000445.5) | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV100510021; called by muse, mutect2, varscan2
- PLEC | c.10114G>C p.E3372Q (on ENST00000322810 / NM_201380.4; = p.E3262Q on NM_000445.5) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100510027; called by muse, mutect2, varscan2
- PLEC | c.9688G>A p.E3230K (on ENST00000322810 / NM_201380.4; = p.E3120K on NM_000445.5) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100510034, COSV59658748; called by muse, mutect2, varscan2
- PLEC | c.9304G>A p.E3102K (on ENST00000322810 / NM_201380.4; = p.E2992K on NM_000445.5) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs782058888, COSV100510039; called by muse, mutect2, varscan2
- PLEC | c.7153G>A p.E2385K (on ENST00000322810 / NM_201380.4; = p.E2275K on NM_000445.5) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1554691569, COSV100510051, COSV59667101, COSV59697472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.6754G>A p.E2252K (on ENST00000322810 / NM_201380.4; = p.E2142K on NM_000445.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs782713908, COSV59640479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.6370G>A p.E2124K (on ENST00000322810 / NM_201380.4; = p.E2014K on NM_000445.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100510084; called by muse, mutect2
- PLEC | c.6298G>C p.E2100Q (on ENST00000322810 / NM_201380.4; = p.E1990Q on NM_000445.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs1554695422, COSV100510091; called by muse, varscan2
- PLEC | c.6244G>C p.E2082Q (on ENST00000322810 / NM_201380.4; = p.E1972Q on NM_000445.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100510095; called by muse, varscan2
- POM121L12 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV101374833, COSV101374936; called by muse, mutect2
- PRKCI | c.1148A>T p.N383I | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855608; called by muse, mutect2, varscan2
- PRPF31 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100319849; called by muse, mutect2, varscan2
- PRRC2C | c.916G>A p.E306K (on ENST00000367742; = p.E304K on NM_015172.4) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100144608; called by muse, mutect2, varscan2
- PRSS48 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV101490156; called by muse, mutect2, varscan2
- PSMD3 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 149/388 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1035110947, COSV52857814; called by muse, mutect2, varscan2
- PTPDC1 | c.1076G>A p.R359Q (on ENST00000375360 / NM_177995.3; = p.R411Q on NM_152422.4) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756453825, COSV56622453, COSV99997312; called by muse, mutect2, varscan2
- PTPMT1 | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100442809, COSV100442862; called by muse, mutect2, varscan2
- RAET1L | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV99657696; called by muse, mutect2, varscan2
- RARA | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as COSV99564463; called by muse, mutect2, varscan2
- RGS22 | c.2311C>T p.L771F | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100692959, COSV62669221; called by muse, mutect2, varscan2
- RHOBTB3 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368331385; called by muse, mutect2, varscan2
- RIMS3 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149583022; called by muse, mutect2, varscan2
- SAMM50 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 138/586 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100601220; called by muse, varscan2
- SCN10A | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 129/237 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs764007884, COSV101479222; called by muse, mutect2, varscan2
- SFRP4 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 162/437 reads (37%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV101460867; called by muse, mutect2, varscan2
- SLC26A3 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs765288477, COSV60641616; called by muse, mutect2, varscan2
- SLC4A10 | c.2894C>T p.P965L (on ENST00000446997 / NM_001354461.2; = p.P935L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99762176; called by muse, mutect2, varscan2
- SMPD1 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as CD041946, COSV100192288; called by muse, mutect2, varscan2
- SOGA1 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV99412628; called by muse, mutect2, varscan2
- SORCS3 | c.3529G>A p.A1177T | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs140421862; called by muse, mutect2, varscan2
- SRBD1 | c.1363T>A p.S455T | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs762131349, COSV99764603; called by muse, mutect2, varscan2
- SVIL | c.5427G>C p.E1809D (on ENST00000355867 / NM_021738.3; = p.E1383D on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100880847; called by muse, mutect2, varscan2
- SYF2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs756540517, COSV52573991; called by muse, mutect2, varscan2
- TM7SF3 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1277083382, COSV58002070, COSV58003732; called by muse, mutect2, varscan2
- TPX2 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100301478; called by muse, mutect2
- TWF2 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV100564439, COSV59726847; called by muse, mutect2, varscan2
- UGT2B4 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.492); catalogued as COSV100522164, COSV59317176; called by muse, mutect2, varscan2
- VIRMA | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99887519; called by muse, mutect2, varscan2
- VPS11 | c.683G>A p.R228K (on ENST00000620429; = p.R772K on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100333489; called by muse, mutect2, varscan2
- WDR27 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100358052; called by muse, mutect2, varscan2
- ZNF317 | c.1582A>T p.K528* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV99926784; called by muse, mutect2, varscan2
- ZNF358 | c.60A>T p.E20D | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99900342; called by muse, mutect2, varscan2
- ZNF570 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100355996; called by muse, mutect2, varscan2
- ZNF804B | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as COSV100301575; called by muse, mutect2, varscan2
- BABAM1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- BIRC6 | c.6612dup p.N2205* | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- CUBN | c.4966C>G p.P1656A | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- NSD1 | c.1768_1769del p.L590Ifs*5 | Frame Shift Del (DEL) | VAF 68/168 reads (40%) | called by mutect2, pindel, varscan2
- PLEC | c.8326delinsAA p.E2776Kfs*70 (on ENST00000322810 / NM_201380.4; = p.E2666Kfs*70 on NM_000445.5) | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by pindel, varscan2*
- RFPL4B | c.629dup p.L211Pfs*4 | Frame Shift Ins (INS) | VAF 30/144 reads (21%) | called by mutect2, pindel, varscan2
- CHN1 | c.390A>T p.A130= | Silent (SNP) | VAF 31/281 reads (11%) | catalogued as COSV101303523; called by muse, mutect2, varscan2
- DCAF4L2 | c.588G>A p.A196= | Silent (SNP) | VAF 58/243 reads (24%) | catalogued as rs760989849, COSV60479866, COSV60482852; called by muse, mutect2, varscan2
- DHX36 | c.1377A>G p.V459= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV100273266; called by muse, mutect2, varscan2
- DPYSL4 | c.54G>A p.L18= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs137897999; called by muse, mutect2, varscan2
- EHD3 | c.654G>C p.L218= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100434604; called by muse, mutect2, varscan2
- ERICH3 | c.3588G>A p.L1196= | Silent (SNP) | VAF 143/364 reads (39%) | catalogued as COSV100443267, COSV58620023; called by muse, mutect2, varscan2
- EXTL1 | c.483C>T p.V161= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV100959048; called by muse, mutect2, varscan2
- FTSJ3 | c.499C>T p.L167= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100037142; called by muse, mutect2
- GAST | c.204C>A p.L68= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100267999, COSV61475691; called by muse, mutect2, varscan2
- IZUMO1R | c.81C>T p.C27= | Silent (SNP) | VAF 66/134 reads (49%) | catalogued as rs1386991406, COSV100126789; called by muse, mutect2, varscan2
- KCNA1 | c.1413C>G p.V471= | Silent (SNP) | VAF 46/296 reads (16%) | catalogued as rs768963686, COSV101230098, COSV66837103; called by muse, mutect2, varscan2
- LEFTY2 | c.606G>A p.S202= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs769164420, COSV100832523; called by muse, varscan2
- LRRC30 | c.780C>T p.I260= | Silent (SNP) | VAF 190/425 reads (45%) | catalogued as rs570090261, COSV67301433; called by muse, varscan2
- MAP3K8 | c.1332C>T p.L444= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as COSV99551899; called by muse, mutect2, varscan2
- MCMDC2 | c.873C>T p.L291= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as COSV100551634; called by muse, mutect2, varscan2
- NBEAL2 | c.2310C>T p.S770= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs867290897, COSV52761319; called by muse, mutect2, varscan2
- NMRAL1 | c.105G>A p.V35= | Silent (SNP) | VAF 162/513 reads (32%) | catalogued as COSV99361624; called by muse, mutect2, varscan2
- NOA1 | c.624G>C p.A208= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99950398; called by muse, mutect2
- ODF2 | c.2118G>A p.R706= (on ENST00000434106 / NM_153433.2; = p.R682= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100654409; called by muse, varscan2
- PHLDB2 | c.3417A>G p.V1139= (on ENST00000393925 / NM_001134439.2; = p.V1096= on NM_145753.2) | Silent (SNP) | VAF 64/209 reads (31%) | catalogued as rs768412064, COSV67313401; called by muse, mutect2, varscan2
- PLEC | c.8562G>A p.Q2854= (on ENST00000322810 / NM_201380.4; = p.Q2744= on NM_000445.5) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100510046; called by muse, mutect2, varscan2
- PLEC | c.7047G>A p.L2349= (on ENST00000322810 / NM_201380.4; = p.L2239= on NM_000445.5) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs782196411, COSV100510055; called by muse, varscan2
- PLEC | c.6162G>C p.L2054= (on ENST00000322810 / NM_201380.4; = p.L1944= on NM_000445.5) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100510117; called by muse, varscan2
- PLEC | c.5979C>T p.L1993= (on ENST00000322810 / NM_201380.4; = p.L1883= on NM_000445.5) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100510121, COSV100511698; called by muse, mutect2, varscan2
- PYGM | c.1593C>T p.F531= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV99376687; called by muse, mutect2, varscan2
- RELL1 | c.726G>A p.R242= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100025232; called by muse, mutect2, varscan2
- RELL2 | c.645G>C p.G215= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV51837879, COSV99781138; called by muse, mutect2, varscan2
- RYR2 | c.8472G>T p.R2824= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100767545; called by muse, mutect2, varscan2
- SLC4A2 | c.1518G>T p.L506= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100054792; called by muse, mutect2, varscan2
- SLC4A2 | c.1519C>T p.L507= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1455615899, COSV100054793; called by muse, mutect2, varscan2
- TAOK1 | c.1665G>A p.Q555= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as COSV99913455; called by muse, mutect2
- UHRF1 | c.723G>A p.A241= (on ENST00000612630 / NM_001290050.1; = p.A254= on NM_013282.4) | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs769707191, COSV99503272; called by muse, mutect2, varscan2
- UNC5C | c.2526C>T p.F842= | Silent (SNP) | VAF 106/533 reads (20%) | catalogued as COSV101497770; called by muse, mutect2, varscan2
- USP49 | c.1245C>G p.L415= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs758457104, COSV99789837; called by muse, mutect2, varscan2
- VPS13B | c.474C>G p.L158= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as COSV100660778; called by muse, mutect2, varscan2
- XKR4 | c.345C>T p.I115= | Silent (SNP) | VAF 53/113 reads (47%) | catalogued as rs752249026, COSV100530599; called by muse, mutect2, varscan2
- IL36B | c.261+993G>A | Intron (SNP) | VAF 15/102 reads (15%) | catalogued as rs780761547, COSV99382440; called by muse, mutect2, varscan2
